Somatic mutation profile of tumor specimen ALCH-B1PX-TTP1-A (aliquot ALCH-B1PX-TTP1-A-2-0-D-A76C-36) from ALCHEMIST case ALCH-B1PX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.7 years (19,979 days).
Specimen ALCH-B1PX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b985f0c-47f8-4609-bf97-f7e82e70d182.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1PX-NB1-A (Blood Derived Normal), aliquot ALCH-B1PX-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5a4ecff-8c25-4b4e-8036-b5fe243e397e

The open-access MAF lists 4,727 somatic variants for this specimen: 3,276 protein-altering or splice-affecting, 901 silent, 550 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,788, Silent 901, Nonsense Mutation 238, Intron 237, Splice Site 102, RNA 84, 5'UTR 83, Frame Shift Del 76, 3'UTR 70, 5'Flank 58, Splice Region 42, Frame Shift Ins 21.

Variants (750 of 4,727; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.2987+1G>A p.X996_splice | Splice Site (SNP) | VAF 55/345 reads (16%) | catalogued as rs1555370248; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.1704+1G>A p.X568_splice | Splice Site (SNP) | VAF 60/184 reads (33%) | catalogued as rs794727123, CS140197, CS150624; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRT12 | c.427G>C p.V143L | Missense Mutation (SNP) | VAF 114/415 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs58343600, CM085505, CM970837; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- RAB27A | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 42/307 reads (14%) | catalogued as rs104894500, CM045548; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RECQL4 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 44/376 reads (12%) | catalogued as rs1554902528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMPD4 | c.462+1G>T p.X154_splice | Splice Site (SNP) | VAF 26/250 reads (10%) | catalogued as rs780446128, COSV100302258; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.920-1G>T p.X307_splice | Splice Site (SNP) | VAF 110/257 reads (43%) | hotspot (GDC flag); catalogued as rs587781702, CS0910927, CS114009, COSV52664150, COSV52690279, COSV52737535; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A3GALT2 | c.844C>A p.R282S | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as rs576547558, COSV57760353; called by muse, mutect2, varscan2
- ABCA8 | c.2667A>G p.I889M | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as rs890161897; called by muse, mutect2
- ACP7 | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs765034834, COSV58699121; called by muse, mutect2, varscan2
- ACSL4 | c.701A>G p.N234S (on ENST00000340800 / NM_022977.2; = p.N193S on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1379206049, COSV61613364; called by muse, mutect2, varscan2
- ACSM4 | c.535G>T p.V179L | Missense Mutation (SNP) | VAF 32/667 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV68067848; called by muse, mutect2
- ACSS3 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV99698962; called by muse, mutect2
- ACTN2 | c.2507G>T p.R836L | Missense Mutation (SNP) | VAF 144/715 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV63978997; called by muse, mutect2, varscan2
- ADAM30 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65561122; called by muse, mutect2
- ADAM32 | c.1038G>T p.M346I | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65951870; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1177C>G p.R393G | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV56477136; called by mutect2, varscan2
- ADAMTS12 | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 128/490 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs368311933; called by muse, mutect2, varscan2
- ADAMTS17 | c.2276A>T p.K759I | Missense Mutation (SNP) | VAF 181/669 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as rs553411610; called by muse, mutect2, varscan2
- ADAMTS19 | c.3529G>A p.V1177M | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99177124; called by muse, mutect2
- ADAMTS6 | c.2787G>C p.K929N | Missense Mutation (SNP) | VAF 97/587 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.579); catalogued as COSV58684563; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1072+1G>T p.X358_splice | Splice Site (SNP) | VAF 95/530 reads (18%) | catalogued as COSV54435883, COSV99717531; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3218G>T p.W1073L | Missense Mutation (SNP) | VAF 110/490 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV54469772; called by muse, mutect2, varscan2
- ADCY1 | c.1761C>G p.F587L | Missense Mutation (SNP) | VAF 70/334 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99812212; called by muse, mutect2, varscan2
- ADCY9 | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs779278647; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 81/391 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs1450512891; called by muse, mutect2, varscan2
- ADGB | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.326); catalogued as rs377313716, COSV58855553; called by muse, mutect2, varscan2
- ADGRA1 | c.1308C>A p.Y436* | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | catalogued as COSV99077937; called by muse, mutect2, varscan2
- ADGRA2 | c.3955G>A p.A1319T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs1386026966; called by muse, mutect2, varscan2
- ADGRB3 | c.343A>T p.K115* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV65403297; called by muse, mutect2, varscan2
- ADGRB3 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV101001631; called by muse, mutect2, varscan2
- ADGRD2 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58339596; called by muse, mutect2, varscan2
- ADGRF3 | c.2975C>T p.T992I (on ENST00000311519 / NM_001145168.1; = p.T793I on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 157/507 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1184120595; called by muse, mutect2, varscan2
- ADGRF4 | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as rs112563187, COSV51954824; called by muse, mutect2, varscan2
- ADGRL2 | c.183C>A p.S61R | Missense Mutation (SNP) | VAF 58/379 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.787); catalogued as rs769350694; called by muse, mutect2, varscan2
- ADGRL2 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV99591822; called by muse, mutect2
- ADGRL2 | c.2035G>T p.G679* (on ENST00000370717 / NM_001366005.1; = p.G666* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 34/183 reads (19%) | catalogued as COSV99588967; called by muse, mutect2, varscan2
- ADGRL3 | c.4285C>A p.L1429M (on ENST00000506720 / NM_001322402.2; = p.L1318M on NM_015236.6) | Missense Mutation (SNP) | VAF 75/373 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV72230776; called by muse, mutect2, varscan2
- ADGRL4 | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.116); catalogued as rs759189809; called by mutect2, varscan2
- ADH1B | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 54/502 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV59296649; called by muse, varscan2
- ADRB3 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 63/552 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100799821; called by muse, mutect2, varscan2
- AFM | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV99888906; called by muse, mutect2, varscan2
- AGBL1 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs182802715, COSV69797597; called by muse, mutect2, varscan2
- AHCTF1 | c.1869G>A p.W623* (on ENST00000366508; = p.W597* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 33/222 reads (15%) | catalogued as COSV58254223; called by muse, mutect2, varscan2
- AICDA | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57563422, COSV57566722; called by muse, mutect2, varscan2
- AKAP17A | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.928); catalogued as COSV58311130; called by muse, mutect2, varscan2
- AKAP3 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs370794366; called by muse, mutect2, varscan2
- AKR7L | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs541848639; called by muse, mutect2, varscan2
- AKT3 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 21/158 reads (13%) | catalogued as COSV55630253; called by muse, mutect2, varscan2
- ALDH16A1 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.743); catalogued as COSV53192742; called by muse, mutect2, varscan2
- ALG10 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56791977; called by muse, mutect2
- AMH | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs763578155, COSV99677634; called by muse, mutect2, varscan2
- AMY2B | c.1516C>A p.H506N | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100796471, COSV63716137; called by muse, varscan2
- ANAPC1 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1195556622; called by muse, mutect2
- ANK2 | c.90C>G p.D30E | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52157124; called by muse, mutect2
- ANKH | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 224/851 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV99414360; called by muse, mutect2, varscan2
- ANKRD60 | c.727G>T p.G243* | Nonsense Mutation (SNP) | VAF 31/163 reads (19%) | catalogued as COSV64518361; called by muse, mutect2, varscan2
- ANXA11 | c.859-1G>T p.X287_splice | Splice Site (SNP) | VAF 29/91 reads (32%) | catalogued as COSV55416714; called by muse, mutect2, varscan2
- APC | c.4431G>T p.Q1477H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57332269; called by muse, mutect2, varscan2
- APOA4 | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.202); catalogued as COSV63361017; called by muse, mutect2
- APOL2 | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.712); catalogued as rs748031710, COSV50772626; called by muse, mutect2, varscan2
- APP | c.2266G>T p.G756C | Missense Mutation (SNP) | VAF 65/932 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60999058; called by muse, mutect2
- AR | c.2111G>C p.S704T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as BM1260373, COSV101017787; called by muse, mutect2
- AR | c.2741C>A p.P914H | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as CM100922, COSV101019895; called by muse, mutect2, varscan2
- ARHGEF16 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 26/242 reads (11%) | catalogued as COSV65683429; called by muse, mutect2, varscan2
- ARHGEF28 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201772688; called by mutect2, varscan2
- ARID1A | c.3820G>A p.G1274R | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61371474; called by muse, mutect2, varscan2
- ARID1B | c.5476G>T p.E1826* | Nonsense Mutation (SNP) | VAF 72/236 reads (31%) | catalogued as rs1554237408; called by muse, mutect2, varscan2
- ARID2 | c.284+1G>T p.X95_splice | Splice Site (SNP) | VAF 26/186 reads (14%) | catalogued as COSV57608283; called by muse, mutect2, varscan2
- ARMH4 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as rs1368753776; called by muse, mutect2
- ARNT2 | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 86/628 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM141148; called by muse, mutect2, varscan2
- ASB12 | c.377del p.L126Wfs*34 | Frame Shift Del (DEL) | VAF 64/387 reads (17%) | catalogued as rs1418709370; called by mutect2, pindel, varscan2
- ASTN1 | c.2168C>A p.T723N | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV56077242; called by muse, mutect2, varscan2
- ASTN1 | c.299C>G p.T100R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV56080719, COSV99922120; called by muse, mutect2
- ASXL3 | c.977-1G>T p.X326_splice | Splice Site (SNP) | VAF 22/85 reads (26%) | catalogued as COSV99322769; called by muse, mutect2, varscan2
- ATAD3B | c.668G>C p.R223P (on ENST00000308647; = p.R329P on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs202199929; called by muse, mutect2, varscan2
- ATP11B | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV60032694; called by muse, mutect2
- ATP12A | c.2311G>T p.A771S | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs750121465, COSV54512200; called by muse, mutect2, varscan2
- ATP2B3 | c.3524del p.P1175Rfs*12 | Frame Shift Del (DEL) | VAF 49/154 reads (32%) | catalogued as rs782513834; called by mutect2, pindel, varscan2
- ATP5MF | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.985); catalogued as rs774879106; called by muse, mutect2
- ATP8A2 | c.1184G>T p.W395L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.385); catalogued as COSV54972281; called by muse, mutect2, varscan2
- ATRX | c.4280G>C p.R1427P | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64876059; called by muse, mutect2, varscan2
- AUTS2 | c.3167C>A p.P1056Q | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61422573; called by muse, varscan2
- B3GAT2 | c.168G>T p.R56S | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs760672632; called by muse, mutect2
- BAG5 | c.860G>C p.R287T | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.355); catalogued as rs777828990; called by muse, mutect2, varscan2
- BARD1 | c.1905G>T p.W635C | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773223671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BATF | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1335713966; called by muse, mutect2, varscan2
- BAZ1A | c.3599G>T p.R1200L | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62410024; called by muse, mutect2, varscan2
- BBX | c.2815G>T p.A939S (on ENST00000325805 / NM_001142568.3; = p.A909S on NM_020235.7) | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57883065; called by muse, varscan2
- BEX5 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 25/132 reads (19%) | catalogued as COSV61328585; called by muse, mutect2, varscan2
- BICC1 | c.2840G>T p.R947L | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV65855950; called by muse, mutect2, varscan2
- BPIFA2 | c.646-1G>T p.X216_splice | Splice Site (SNP) | VAF 26/312 reads (8%) | catalogued as COSV53611538; called by muse, mutect2
- BPIFB4 | c.543T>G p.D181E | Missense Mutation (SNP) | VAF 62/366 reads (17%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as COSV64950773; called by muse, varscan2
- BRAT1 | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 70/395 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV61393952; called by muse, mutect2, varscan2
- BTG1 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 41/397 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99755832; called by muse, mutect2, varscan2
- BTNL9 | c.1425C>G p.H475Q | Missense Mutation (SNP) | VAF 78/490 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as rs753334630, COSV59795801; called by muse, mutect2, varscan2
- BUD13 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52767165; called by muse, mutect2
- C10orf120 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV61492478, COSV61492634; called by muse, mutect2, varscan2
- C10orf71 | c.1043C>A p.P348H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100109714; called by muse, mutect2, varscan2
- C12orf43 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs137945188; called by muse, mutect2, varscan2
- C16orf95 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV53679357; called by muse, mutect2, varscan2
- C16orf96 | c.1324C>A p.Q442K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV101474585; called by muse, mutect2, varscan2
- C1QC | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 49/457 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.145); catalogued as rs772221556, COSV65889392; called by muse, mutect2, varscan2
- C2CD5 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 56/465 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61722731; called by muse, mutect2, varscan2
- C4orf54 | c.2813G>T p.R938L | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs772764932; called by muse, mutect2, varscan2
- C6orf58 | c.521G>T p.S174I | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100314664; called by muse, mutect2, varscan2
- C8A | c.554G>T p.W185L | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63483442; called by muse, mutect2
- C9orf24 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.859); catalogued as COSV52625750; called by muse, mutect2, varscan2
- CACNA1B | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 87/370 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs202180847; called by muse, mutect2, varscan2
- CACNA1C | c.3235G>C p.G1079R | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59766943; called by muse, varscan2
- CACNA1C | c.3238G>T p.E1080* | Nonsense Mutation (SNP) | VAF 26/198 reads (13%) | catalogued as rs1555882476; called by muse, varscan2
- CACNA1C | c.4918G>T p.V1640L | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV59741780; called by muse, mutect2, varscan2
- CACNA1E | c.2020A>T p.S674C | Missense Mutation (SNP) | VAF 74/333 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.754); catalogued as rs779138664; called by muse, mutect2, varscan2
- CACNA1E | c.6346C>A p.R2116S (on ENST00000367573 / NM_001205293.3; = p.R2073S on NM_000721.4) | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.11); catalogued as COSV62382695; called by muse, mutect2, varscan2
- CACNB2 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.015); catalogued as rs377258255; called by muse, mutect2, varscan2
- CALHM4 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1272525866, COSV63985658; called by muse, mutect2, varscan2
- CAMK1D | c.992C>G p.S331* | Nonsense Mutation (SNP) | VAF 74/396 reads (19%) | catalogued as COSV66611671; called by muse, mutect2, varscan2
- CAPN13 | c.2001G>C p.M667I | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs1404876251; called by muse, mutect2
- CASR | c.1712G>T p.R571L (on ENST00000490131; = p.R648L on NM_000388.4) | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.56); catalogued as rs757736220; called by muse, mutect2, varscan2
- CASS4 | c.726G>T p.W242C | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64387989; called by muse, mutect2, varscan2
- CBL | c.2079G>T p.E693D | Missense Mutation (SNP) | VAF 35/363 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV99876247; called by muse, mutect2, varscan2
- CBWD6 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 54/587 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs771756067; called by muse, mutect2, varscan2
- CCDC136 | c.592T>A p.S198T | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs1466117244; called by muse, mutect2, varscan2
- CCDC136 | c.3438G>T p.W1146C | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1381171736; called by muse, mutect2
- CCDC141 | c.3206G>T p.R1069M | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55371681; called by muse, varscan2
- CCDC172 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100319617; called by muse, mutect2, varscan2
- CCDC178 | c.1400C>A p.T467N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs760077046, COSV55767541; called by muse, mutect2
- CCDC178 | c.1228C>A p.H410N | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100285556; called by muse, mutect2, varscan2
- CCDC190 | c.695A>G p.E232G | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs1558110316; called by muse, mutect2, varscan2
- CCDC7 | c.2437C>A p.P813T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV100179174; called by muse, mutect2, varscan2
- CCDC85A | c.1520G>C p.S507T | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.108); catalogued as COSV68154254; called by muse, mutect2, varscan2
- CCDC91 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV100082599; called by muse, mutect2, varscan2
- CCDC92 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.279); catalogued as rs762582864, COSV53020143; called by muse, mutect2, varscan2
- CCKBR | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as COSV58099782; called by muse, mutect2, varscan2
- CCN4 | c.490C>A p.R164S | Missense Mutation (SNP) | VAF 56/514 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.738); catalogued as COSV51532362; called by muse, varscan2
- CCNB2 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227439754; called by muse, mutect2, varscan2
- CCND2 | c.770G>T p.S257I | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV54223287; called by muse, mutect2
- CCSER2 | c.2465G>T p.G822V | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56509644, COSV56513993; called by muse, mutect2, varscan2
- CCT8L2 | c.633dup p.T212Dfs*52 | Frame Shift Ins (INS) | VAF 21/196 reads (11%) | catalogued as rs767593972; called by mutect2, pindel, varscan2
- CD200R1 | c.460G>C p.E154Q (on ENST00000471858 / NM_170780.3; = p.E177Q on NM_138806.4) | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55599361; called by muse, mutect2, varscan2
- CD200R1L | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.322); catalogued as COSV101236611; called by mutect2, varscan2
- CD226 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV99711230; called by muse, mutect2
- CDH12 | c.281C>A p.S94* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as COSV66419682; called by muse, mutect2
- CDH15 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228474; called by muse, mutect2, varscan2
- CDH24 | c.143G>T p.W48L | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99400101; called by muse, mutect2
- CDH5 | c.162G>T p.M54I | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV58515584; called by muse, mutect2
- CDK20 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 34/384 reads (9%) | catalogued as COSV100308066; called by muse, mutect2
- CELA2A | c.492G>C p.Q164H | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100657489; called by muse, mutect2, varscan2
- CEP126 | c.354C>G p.F118L | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54827597, COSV54828955; called by muse, mutect2, varscan2
- CEP128 | c.2576T>C p.I859T | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs1295479601; called by muse, mutect2
- CERCAM | c.1495G>T p.V499L | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65711241; called by muse, mutect2, varscan2
- CFAP47 | c.4206C>A p.D1402E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.143); catalogued as COSV57971218; called by muse, mutect2, varscan2
- CFAP92 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 54/417 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1373579452, COSV54047833; called by muse, mutect2, varscan2
- CFAP99 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 30/277 reads (11%) | catalogued as rs780469921; called by muse, mutect2, varscan2
- CFH | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV66410937; called by muse, mutect2
- CH25H | c.191G>T p.W64L | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV64092497; called by muse, mutect2
- CHAT | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 79/660 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs971900143, COSV100340420; called by muse, mutect2, varscan2
- CHI3L2 | c.653G>T p.W218L | Missense Mutation (SNP) | VAF 36/502 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV63873908; called by muse, mutect2
- CHRM3 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55080494; called by muse, mutect2, varscan2
- CHRNB2 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 168/836 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV63808138; called by muse, mutect2, varscan2
- CHST11 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 42/452 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.054); catalogued as COSV57985752; called by muse, mutect2
- CHST13 | c.576C>A p.Y192* | Nonsense Mutation (SNP) | VAF 63/221 reads (29%) | catalogued as COSV60041350; called by muse, mutect2, varscan2
- CLCA1 | c.1501T>C p.W501R | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1169645683; called by muse, mutect2, varscan2
- CLCNKB | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV65160209; called by muse, mutect2, varscan2
- CLPS | c.105G>T p.M35I | Missense Mutation (SNP) | VAF 75/532 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV52566881; called by muse, mutect2, varscan2
- CLSTN2 | c.128G>C p.W43S | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101515506, COSV71722203; called by muse, varscan2
- CLU | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 136/509 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV57067134; called by muse, mutect2, varscan2
- CNTN2 | c.1316C>A p.P439H | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs761643020; called by muse, mutect2, varscan2
- CNTNAP2 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 88/329 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs750876987; called by muse, mutect2, varscan2
- CNTNAP2 | c.1221T>A p.N407K | Missense Mutation (SNP) | VAF 96/444 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.281); catalogued as rs777201584; called by muse, mutect2, varscan2
- CNTNAP2 | c.1482G>C p.E494D | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.017); catalogued as COSV62162837; called by muse, varscan2
- COBL | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 99/328 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as rs1482774465, COSV104371318; called by muse, mutect2, varscan2
- COL11A1 | c.3253C>A p.P1085T | Missense Mutation (SNP) | VAF 46/634 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1352895098, COSV62180011; called by muse, mutect2
- COL11A1 | c.3025-1G>T p.X1009_splice | Splice Site (SNP) | VAF 21/191 reads (11%) | catalogued as COSV62195317; called by muse, mutect2, varscan2
- COL11A1 | c.2966C>A p.P989H | Missense Mutation (SNP) | VAF 63/383 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62189563; called by muse, mutect2, varscan2
- COL11A1 | c.2453G>T p.R818L | Missense Mutation (SNP) | VAF 81/374 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV99058247; called by muse, mutect2, varscan2
- COL11A1 | c.642A>C p.E214D | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV62187524; called by muse, mutect2
- COL19A1 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1215165426; called by muse, mutect2, varscan2
- COL20A1 | c.2984C>T p.P995L | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV58922690; called by muse, mutect2, varscan2
- COL22A1 | c.4799G>T p.G1600V | Missense Mutation (SNP) | VAF 46/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57328863; called by muse, mutect2, varscan2
- COL27A1 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV61926781; called by muse, mutect2, varscan2
- COL2A1 | c.3815C>A p.P1272H | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100476637; called by muse, mutect2
- COL5A1 | c.2710G>T p.G904* | Nonsense Mutation (SNP) | VAF 40/298 reads (13%) | catalogued as COSV65670375; called by muse, mutect2, varscan2
- COL5A1 | c.3744+1G>T p.X1248_splice | Splice Site (SNP) | VAF 75/620 reads (12%) | catalogued as COSV100879643, COSV65673747; called by muse, mutect2, varscan2
- COL5A2 | c.2138G>C p.R713P | Missense Mutation (SNP) | VAF 92/259 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV66410354, COSV66410598; called by muse, varscan2
- COL5A3 | c.1204del p.V402Wfs*41 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | catalogued as rs1221114698; called by mutect2, pindel, varscan2
- CPA1 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 103/630 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs200317425; called by muse, mutect2, varscan2
- CPAMD8 | c.398T>A p.I133N (on ENST00000651564; = p.I86N on NM_015692.5) | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs757289775; called by muse, mutect2, varscan2
- CPED1 | c.2579G>A p.G860D | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60013872; called by muse, mutect2, varscan2
- CPZ | c.232G>C p.E78Q (on ENST00000360986 / NM_001014447.3; = p.E67Q on NM_003652.3) | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748204322, COSV59924051; called by muse, mutect2, varscan2
- CRB2 | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as rs759937525; called by muse, mutect2, varscan2
- CRCT1 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 107/461 reads (23%) | PolyPhen benign (0.102); catalogued as rs374162866, COSV57500797; called by muse, mutect2, varscan2
- CRIM1 | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV54861239; called by muse, mutect2, varscan2
- CRISP3 | c.88C>G p.P30A (on ENST00000371159 / NM_001368123.1; = p.P22A on NM_001190986.2) | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); catalogued as COSV53822712; called by muse, mutect2, varscan2
- CRYGA | c.252+1G>A p.X84_splice | Splice Site (SNP) | VAF 23/163 reads (14%) | catalogued as COSV58016663; called by muse, mutect2, varscan2
- CSMD1 | c.9266G>T p.S3089I (on ENST00000520002; = p.S3088I on NM_033225.6) | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV59331146; called by muse, mutect2, varscan2
- CSMD1 | c.1858G>T p.G620* (on ENST00000520002; = p.G619* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 18/188 reads (10%) | catalogued as COSV59376189; called by muse, mutect2
- CSMD2 | c.2075del p.P692Rfs*7 | Frame Shift Del (DEL) | VAF 38/151 reads (25%) | catalogued as COSV53921902; called by mutect2, pindel, varscan2
- CSMD3 | c.10222C>G p.P3408A (on ENST00000297405 / NM_001363185.1; = p.P3239A on NM_052900.3) | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.11); catalogued as COSV52324767; called by muse, mutect2, varscan2
- CT47B1 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.556); catalogued as COSV100988972, COSV64890515, COSV64891306; called by muse, mutect2, varscan2
- CTNNA3 | c.1537C>A p.H513N | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101044492; called by muse, mutect2, varscan2
- CUBN | c.10173G>T p.Q3391H | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV64715841; called by muse, mutect2
- CUBN | c.8681C>A p.P2894Q | Missense Mutation (SNP) | VAF 42/711 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV100912800; called by muse, mutect2
- CYP2A13 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV57837091; called by muse, mutect2, varscan2
- CYP2A6 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs139639589; called by muse, mutect2, varscan2
- CYP2B6 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 57/494 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as rs200458614, COSV57845135, COSV57845291; called by muse, mutect2, varscan2
- CYP4F22 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs139927884; called by muse, mutect2, varscan2
- D2HGDH | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 14/148 reads (9%) | catalogued as COSV58318986; called by muse, mutect2
- DAGLA | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1417305178; called by muse, mutect2
- DCC | c.2643C>A p.Y881* | Nonsense Mutation (SNP) | VAF 156/486 reads (32%) | catalogued as COSV100497710; called by muse, mutect2, varscan2
- DCLK3 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV69363204; called by muse, mutect2, varscan2
- DDC | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 106/768 reads (14%) | catalogued as COSV63566136; called by muse, mutect2, varscan2
- DDO | c.737C>T p.P246L (on ENST00000368924 / NM_001368172.1; = p.P187L on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.304); catalogued as rs778718857, COSV64470557; called by muse, varscan2
- DDX60L | c.3952C>T p.L1318F | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs1354603979; called by muse, mutect2
- DIP2C | c.2413A>T p.N805Y | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55158482; called by muse, mutect2, varscan2
- DISC1 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 88/484 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.346); catalogued as COSV54401662; called by muse, mutect2, varscan2
- DLC1 | c.2533G>T p.G845C (on ENST00000276297 / NM_001348081.2; = p.G408C on NM_006094.5) | Missense Mutation (SNP) | VAF 16/397 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99363839; called by muse, mutect2
- DLGAP2 | c.1972C>A p.R658S | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.651); catalogued as COSV101421623; called by muse, mutect2
- DLGAP3 | c.2164G>T p.A722S | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52393265; called by muse, mutect2, varscan2
- DMBT1 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as COSV104397098; called by muse, mutect2
- DMBT1 | c.6601C>A p.R2201S (on ENST00000338354 / NM_001377530.1; = p.R1444S on NM_004406.3) | Missense Mutation (SNP) | VAF 48/548 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs374738106, COSV100352073; called by muse, mutect2
- DMD | c.4344+1G>T p.X1448_splice | Splice Site (SNP) | VAF 22/150 reads (15%) | catalogued as rs1172744225; called by muse, mutect2, varscan2
- DMD | c.9del p.W3Cfs*5 | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | catalogued as CM031161; called by mutect2, pindel*, varscan2*
- DNAH11 | c.10179G>C p.W3393C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100177027; called by muse, mutect2, varscan2
- DNAH5 | c.9430G>T p.E3144* | Nonsense Mutation (SNP) | VAF 37/245 reads (15%) | catalogued as COSV54205540; called by muse, mutect2, varscan2
- DNAH6 | c.7276A>G p.I2426V | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.264); catalogued as rs748113624; called by muse, mutect2, varscan2
- DNAH8 | c.13187A>T p.E4396V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs375455553; called by muse, mutect2, varscan2
- DNAH9 | c.4805C>A p.P1602Q | Missense Mutation (SNP) | VAF 66/361 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52361896; called by muse, mutect2, varscan2
- DNAJB7 | c.785T>A p.F262Y | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.367); catalogued as COSV99344384; called by muse, mutect2, varscan2
- DNM1 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57855148; called by muse, mutect2, varscan2
- DNTTIP1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.107); catalogued as COSV65459923; called by muse, mutect2, varscan2
- DOCK7 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 20/196 reads (10%) | catalogued as COSV52019199; called by muse, mutect2, varscan2
- DPF2 | c.1157A>T p.Q386L | Missense Mutation (SNP) | VAF 69/321 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.901); catalogued as COSV99361471; called by muse, mutect2, varscan2
- DPP10 | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs202170246, COSV59695021; called by muse, varscan2
- DPRX | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 137/329 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs201734272; called by muse, varscan2
- DPYS | c.1436G>T p.R479L | Missense Mutation (SNP) | VAF 103/495 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV104417851; called by muse, mutect2, varscan2
- DSE | c.126C>A p.S42R | Missense Mutation (SNP) | VAF 48/560 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); catalogued as rs764311973; called by muse, mutect2
- DSE | c.706G>T p.V236F | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV59062323; called by muse, mutect2, varscan2
- DUOX2 | c.2627C>A p.S876Y | Missense Mutation (SNP) | VAF 142/608 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66532966; called by muse, mutect2, varscan2
- DUOX2 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 44/474 reads (9%) | catalogued as COSV59909086; called by muse, mutect2
- DYSF | c.911A>T p.D304V | Missense Mutation (SNP) | VAF 65/470 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs763604611; called by muse, mutect2, varscan2
- EBF3 | c.1174G>T p.G392* (on ENST00000355311 / NM_001375392.1; = p.G383* on NM_001005463.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/158 reads (20%) | catalogued as COSV62472799; called by muse, mutect2, varscan2
- EBPL | c.587A>T p.Q196L | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV54432033; called by muse, mutect2, varscan2
- ECHS1 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63906813; called by muse, mutect2
- ECT2L | c.1167C>A p.H389Q | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as COSV62887444; called by muse, mutect2, varscan2
- EDNRB | c.1222-2A>G p.X408_splice (on ENST00000377211 / NM_001201397.1; = p.X318_splice on NM_000115.5) | Splice Site (SNP) | VAF 64/291 reads (22%) | catalogued as rs1195558655; called by muse, mutect2, varscan2
- EEA1 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100467999; called by muse, mutect2, varscan2
- EFNB1 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 36/76 reads (47%) | catalogued as COSV99214760; called by muse, mutect2, varscan2
- EGLN3 | c.172del p.D58Tfs*95 | Frame Shift Del (DEL) | VAF 70/326 reads (21%) | catalogued as COSV51654983; called by mutect2, pindel, varscan2
- EGR1 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.812); catalogued as COSV53518056; called by muse, mutect2, varscan2
- EML3 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 63/366 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53885014; called by muse, mutect2, varscan2
- ENAM | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68536137; called by muse, mutect2, varscan2
- ENPP3 | c.2479T>A p.W827R | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396232411, COSV62953224; called by muse, mutect2, varscan2
- EPC2 | c.1785G>T p.R595S | Missense Mutation (SNP) | VAF 126/334 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.355); catalogued as rs1223502446; called by muse, mutect2, varscan2
- EPHA3 | c.262C>G p.P88A | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.298); catalogued as COSV100344260, COSV100344355; called by muse, mutect2, varscan2
- EPHB1 | c.2577C>A p.D859E | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV67661622; called by muse, mutect2, varscan2
- ERC1 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs200160550, COSV100706510, COSV61697421; called by muse, mutect2, varscan2
- ERC1 | c.1799G>T p.R600L (on ENST00000360905 / NM_178040.4; = p.R572L on NM_178039.4) | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61700580; called by muse, mutect2, varscan2
- ERI2 | c.1641dup p.Q548Tfs*7 | Frame Shift Ins (INS) | VAF 23/200 reads (12%) | catalogued as rs1217954690; called by mutect2, varscan2
- ERICH6B | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs907953283, COSV53922914; called by muse, mutect2, varscan2
- ERV3-1 | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372825689; called by mutect2, varscan2
- ERVV-2 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 63/436 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV74153537; called by muse, mutect2, varscan2
- ESRRG | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV63160716; called by muse, mutect2, varscan2
- EXOC6 | c.86+1G>A p.X29_splice | Splice Site (SNP) | VAF 11/84 reads (13%) | catalogued as COSV101038893; called by muse, mutect2, varscan2
- EXT1 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 98/402 reads (24%) | catalogued as CM109059; called by muse, mutect2, varscan2
- EYS | c.2403G>A p.W801* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as rs1424625518; called by muse, mutect2
- EZHIP | c.647G>C p.R216P | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.513); catalogued as rs1557318764; called by muse, mutect2, varscan2
- FABP4 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs141169989; called by muse, mutect2, varscan2
- FAM135B | c.3901G>C p.G1301R | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99420222, COSV99428007; called by muse, mutect2, varscan2
- FAM135B | c.2878C>A p.P960T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV52703413; called by muse, mutect2, varscan2
- FAM160A2 | c.2006C>T p.A669V (on ENST00000449352 / NM_001098794.2; = p.A683V on NM_032127.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs866799938; called by muse, mutect2, varscan2
- FAM20C | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as COSV58232931; called by muse, mutect2, varscan2
- FAM20C | c.260C>A p.T87K | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV58235872; called by muse, mutect2
- FAP | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV51862099, COSV51867397; called by muse, mutect2, varscan2
- FAT1 | c.7870G>A p.D2624N | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71675209, COSV71676326; called by muse, mutect2, varscan2
- FAT3 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.301); catalogued as COSV53076064; called by muse, mutect2, varscan2
- FAT3 | c.4025C>A p.T1342K | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53072072; called by muse, mutect2, varscan2
- FAT3 | c.9873G>A p.G3291= | Splice Region (SNP) | VAF 39/147 reads (27%) | catalogued as rs1248002903; called by muse, mutect2
- FBN2 | c.5950G>T p.V1984L | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as rs1064796333, COSV52532513, COSV52549529; called by muse, mutect2, varscan2
- FBN2 | c.4595-1G>C p.X1532_splice | Splice Site (SNP) | VAF 53/357 reads (15%) | catalogued as COSV52537025; called by muse, mutect2, varscan2
- FBN2 | c.3709C>A p.R1237S | Missense Mutation (SNP) | VAF 46/435 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs746570981, COSV99075148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL17 | c.2045G>A p.R682K | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV62853437; called by muse, mutect2
- FBXO15 | c.1331C>A p.P444Q | Missense Mutation (SNP) | VAF 127/371 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54043808; called by muse, mutect2, varscan2
- FBXW10 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 67/209 reads (32%) | catalogued as rs779813238; called by muse, mutect2, varscan2
- FCGBP | c.4766A>G p.H1589R | Missense Mutation (SNP) | VAF 252/766 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.731); catalogued as rs1289299299; called by muse, varscan2
- FCRLA | c.332C>A p.P111Q (on ENST00000367959; = p.P88Q on NM_032738.4) | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs1174198205; called by muse, varscan2
- FERD3L | c.420C>G p.I140M | Missense Mutation (SNP) | VAF 68/404 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51761593; called by muse, mutect2, varscan2
- FGA | c.1102G>C p.G368R | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs139005577; called by muse, mutect2, varscan2
- FGD1 | c.1902C>A p.S634R | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.18); catalogued as COSV64309564; called by muse, mutect2, varscan2
- FGD5 | c.2026T>G p.S676A | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV53244087; called by muse, mutect2, varscan2
- FIG4 | c.1046A>T p.Q349L | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57789018; called by muse, mutect2, varscan2
- FIZ1 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs965669673; called by muse, mutect2, varscan2
- FLG | c.4252C>A p.P1418T | Missense Mutation (SNP) | VAF 171/798 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as COSV64239167; called by muse, mutect2, varscan2
- FLNC | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs754309921, COSV57953861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.757T>A p.Y253N | Missense Mutation (SNP) | VAF 69/837 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100367659; called by muse, mutect2
- FLRT2 | c.1014G>T p.M338I | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV58146782; called by muse, mutect2, varscan2
- FLT1 | c.1869C>G p.I623M | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV56727227; called by muse, mutect2, varscan2
- FMN2 | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1488752022; called by muse, mutect2, varscan2
- FMN2 | c.2815G>T p.G939* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV60432677; called by mutect2, varscan2
- FMOD | c.444G>T p.R148S | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV61609921; called by muse, mutect2, varscan2
- FOXB2 | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); catalogued as rs1264813256; called by muse, mutect2, varscan2
- FOXF2 | c.968T>G p.M323R | Missense Mutation (SNP) | VAF 72/325 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs887938130; called by muse, mutect2, varscan2
- FSTL4 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 99/470 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV54776503; called by muse, mutect2, varscan2
- FYB1 | c.726G>T p.R242S | Missense Mutation (SNP) | VAF 210/592 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV60951981; called by muse, mutect2, varscan2
- GABRA1 | c.536C>A p.A179D | Missense Mutation (SNP) | VAF 36/381 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV50106377; called by muse, mutect2
- GABRA6 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV50877441; called by muse, varscan2
- GABRA6 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.122); catalogued as COSV50897535; called by muse, mutect2, varscan2
- GABRG1 | c.839C>A p.P280Q | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54962532; called by muse, mutect2, varscan2
- GABRG2 | c.1104G>T p.K368N (on ENST00000361925 / NM_001375343.1; = p.K328N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/450 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62716025, COSV62718360; called by muse, mutect2, varscan2
- GAREM2 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs1285677830; called by muse, mutect2
- GAS1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs1240348643; called by muse, mutect2, varscan2
- GATAD2A | c.742G>T p.V248F | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53065915; called by muse, mutect2, varscan2
- GCN1 | c.2210G>C p.R737P | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV56104001; called by muse, mutect2
- GDAP2 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.618); catalogued as rs1427868404; called by muse, mutect2, varscan2
- GIMAP1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100212128, COSV56188602; called by muse, mutect2
- GJB4 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201808762, COSV100258240; called by muse, mutect2
- GLCCI1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1243180078; called by muse, mutect2, varscan2
- GLI1 | c.2480C>A p.T827K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV57357439; called by muse, mutect2, varscan2
- GLI3 | c.3350C>A p.P1117Q | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.107); catalogued as rs531098202, COSV67887231, COSV67889919; called by muse, mutect2, varscan2
- GLI3 | c.2453G>T p.C818F | Missense Mutation (SNP) | VAF 76/930 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV67887954; called by muse, mutect2
- GLIS1 | c.1613C>G p.A538G | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV56555940; called by muse, mutect2, varscan2
- GLIS1 | c.1253T>G p.L418R | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs575417991; called by muse, mutect2
- GNL2 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as rs1186855483; called by muse, mutect2
- GOLGA8F | c.725C>T p.P242L (on ENST00000526619; = p.P448L on NM_001350920.2) | Missense Mutation (SNP) | VAF 115/980 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs762392076; called by muse, mutect2, varscan2
- GP5 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55464579; called by muse, mutect2, varscan2
- GPR4 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV100546993; called by muse, mutect2
- GRB7 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs200254714; called by muse, mutect2
- GRHL3 | c.463C>G p.L155V (on ENST00000350501 / NM_198174.3; = p.L160V on NM_021180.3) | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.505); catalogued as rs1213099454; called by muse, mutect2
- GRID1 | c.1765G>T p.V589L | Missense Mutation (SNP) | VAF 54/548 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV60030677; called by muse, mutect2
- GRID1 | c.831G>T p.R277S | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60029161; called by muse, mutect2
- GRIK2 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs188057768, COSV59710460; called by muse, mutect2
- GRIP1 | c.1262A>G p.N421S (on ENST00000359742 / NM_001379345.1; = p.N369S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/379 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV54032710; called by muse, mutect2, varscan2
- GRM5 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 111/570 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59589994; called by muse, mutect2, varscan2
- GRM8 | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 70/422 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58833155; called by muse, mutect2, varscan2
- GRM8 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 73/494 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV58815718; called by muse, mutect2, varscan2
- GRXCR1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 19/223 reads (9%) | catalogued as COSV67674489; called by muse, mutect2
- GSTA5 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 157/358 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs1359924281; called by muse, mutect2, varscan2
- GSTM4 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 121/541 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58694749; called by muse, mutect2, varscan2
- GTDC1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99600203; called by muse, mutect2
- GTF2IRD1 | c.502G>T p.G168W | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56087999, COSV56089359; called by muse, mutect2, varscan2
- GUCY1A2 | c.2030G>T p.R677L | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1390362284, COSV56476921, COSV56477435; called by muse, mutect2, varscan2
- H1-4 | c.235C>A p.R79S | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1481520703; called by muse, mutect2
- H2AC21 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 39/431 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.2); catalogued as COSV100479896; called by muse, mutect2
- HAS1 | c.1196C>A p.A399E | Missense Mutation (SNP) | VAF 56/678 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as rs767247063; called by muse, mutect2
- HCAR3 | c.400C>G p.H134D | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63676552; called by muse, mutect2, varscan2
- HCN1 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs1214072611; called by muse, mutect2, varscan2
- HDGFL3 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100220972; called by muse, mutect2, varscan2
- HEATR1 | c.2789C>T p.P930L | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs1294243318; called by muse, varscan2
- HFM1 | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV54032577; called by muse, mutect2
- HHIP | c.1555C>A p.L519I | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56844275; called by muse, mutect2, varscan2
- HHIPL1 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1399065274; called by muse, mutect2, varscan2
- HHIPL2 | c.1946G>T p.S649I | Missense Mutation (SNP) | VAF 54/458 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV58565369; called by muse, mutect2
- HIVEP3 | c.6965G>T p.R2322L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs756963406; called by mutect2, varscan2
- HK1 | c.1935+7A>G | Splice Region (SNP) | VAF 44/553 reads (8%) | catalogued as rs1018018465; called by muse, mutect2
- HMCN1 | c.12799G>T p.G4267* | Nonsense Mutation (SNP) | VAF 33/262 reads (13%) | catalogued as COSV99635810; called by muse, mutect2, varscan2
- HOXB5 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs558529403; called by muse, mutect2, varscan2
- HOXD11 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.884); catalogued as rs1261908486; called by muse, varscan2
- HPD | c.343G>C p.A115P | Missense Mutation (SNP) | VAF 47/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56641134; called by muse, mutect2, varscan2
- HR | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs765545206, COSV100455802; called by muse, mutect2, varscan2
- HSPG2 | c.8288G>A p.R2763H | Missense Mutation (SNP) | VAF 48/522 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs188987688; ClinVar: uncertain significance; called by muse, mutect2
- HTR7 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); catalogued as rs770562747; called by muse, mutect2, varscan2
- HVCN1 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV54371403; called by muse, mutect2, varscan2
- ICE1 | c.2168T>A p.I723K | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99665593; called by muse, mutect2, varscan2
- IFT140 | c.2483del p.G828Afs*18 | Frame Shift Del (DEL) | VAF 60/263 reads (23%) | catalogued as rs1221627009; called by mutect2, pindel, varscan2
- IGHV3-15 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.1); catalogued as rs782438769; called by muse, mutect2, varscan2
- IGHV4-39 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 92/712 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs1397857044; called by muse, varscan2
- IGKV1D-42 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 56/560 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as rs763749261; called by muse, mutect2, varscan2
- IGKV2D-29 | c.271G>C p.G91R | Missense Mutation (SNP) | VAF 53/501 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV72391653; called by muse, mutect2, varscan2
- IGKV5-2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.971); catalogued as rs757497084; called by muse, mutect2, varscan2
- IGLV11-55 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs747060459; called by muse, mutect2, varscan2
- IGSF1 | c.3185G>C p.G1062A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV63837543; called by muse, mutect2, varscan2
- IGSF21 | c.625A>C p.S209R | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.431); catalogued as COSV99246112; called by muse, mutect2, varscan2
- IGSF9 | c.1213G>T p.G405W (on ENST00000368094 / NM_001135050.2; = p.G389W on NM_020789.4) | Missense Mutation (SNP) | VAF 104/447 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63639301; called by muse, mutect2, varscan2
- IHH | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV99838680; called by muse, mutect2, varscan2
- IL13RA2 | c.308C>A p.A103E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1219445525; called by muse, mutect2, varscan2
- IL9R | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54901517; called by muse, mutect2, varscan2
- INSC | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 60/219 reads (27%) | catalogued as COSV65410987; called by muse, mutect2, varscan2
- INSR | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1370875449; called by muse, mutect2, varscan2
- IPO7 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs942272826; called by muse, mutect2, varscan2
- IQCA1 | c.1931A>G p.K644R | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs755819558; called by muse, mutect2, varscan2
- IQSEC2 | c.3048G>T p.L1016F (on ENST00000642864 / NM_001111125.3; = p.L811F on NM_015075.2) | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.796); catalogued as COSV64727544; called by muse, mutect2, varscan2
- IRS4 | c.1563G>T p.Q521H | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV64534075; called by muse, mutect2, varscan2
- ITGA8 | c.920C>A p.T307K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.916); catalogued as COSV65228257; called by mutect2, varscan2
- ITGB4 | c.1762-2A>G p.X588_splice | Splice Site (SNP) | VAF 40/382 reads (10%) | catalogued as COSV99565188; called by muse, mutect2, varscan2
- ITPR1 | c.4745G>T p.R1582L (on ENST00000354582; = p.R1567L on NM_002222.7) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs569597087, COSV56986194; called by muse, mutect2, varscan2
- IVD | c.468G>A p.L156= (on ENST00000651168; = p.L153= on NM_002225.5 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 44/520 reads (8%) | catalogued as rs372974651; called by muse, mutect2
- JARID2 | c.3172A>G p.M1058V | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV59195544; called by muse, mutect2, varscan2
- KCNAB3 | c.242+8G>T | Splice Region (SNP) | VAF 21/136 reads (15%) | catalogued as rs774222899; called by muse, mutect2, varscan2
- KCNH1 | c.1222G>T p.E408* (on ENST00000271751 / NM_172362.3; = p.E381* on NM_002238.4) | Nonsense Mutation (SNP) | VAF 130/705 reads (18%) | catalogued as COSV55069391, COSV55081940; called by muse, mutect2, varscan2
- KCNH1 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99660731; called by muse, mutect2, varscan2
- KCNJ14 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs992971743; called by muse, mutect2, varscan2
- KCNT2 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54104625, COSV54105199; called by muse, mutect2, varscan2
- KCNU1 | c.3223C>G p.P1075A | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV67756712; called by muse, mutect2
- KDM5D | c.1984A>G p.I662V | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as rs1201540443; called by muse, varscan2
- KDR | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV55760711; called by muse, mutect2, varscan2
- KHSRP | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV67919546; called by muse, mutect2, varscan2
- KIF21B | c.3179del p.G1060Afs*3 | Frame Shift Del (DEL) | VAF 60/295 reads (20%) | catalogued as COSV100144289; called by mutect2, pindel, varscan2
- KIF2B | c.1432C>A p.L478I | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991737337; called by muse, mutect2, varscan2
- KIR3DL1 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 92/725 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs770345968, COSV100428789; called by muse, mutect2, varscan2
- KIT | c.2485G>T p.A829S | Missense Mutation (SNP) | VAF 22/351 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV55414160; called by muse, mutect2
- KLHDC1 | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100833598; called by muse, mutect2, varscan2
- KLHL30 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1458407821; called by mutect2, varscan2
- KLHL40 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV55134059; called by muse, mutect2, varscan2
- KLK15 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56828354; called by muse, mutect2
- KMT2A | c.3596G>T p.W1199L | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV63288207; called by muse, mutect2
- KMT2C | c.7702G>A p.G2568R | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs992402398, COSV51276889; called by muse, mutect2
- KMT2D | c.4865G>T p.G1622V | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99040249; called by muse, mutect2
- KPRP | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as rs763479865, COSV64223128; called by muse, mutect2, varscan2
- KRT2 | c.597G>T p.L199F | Missense Mutation (SNP) | VAF 71/464 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781465953; called by muse, mutect2, varscan2
- KRTAP9-4 | c.68G>C p.C23S | Missense Mutation (SNP) | VAF 118/364 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV61898430; called by muse, varscan2
- KSR2 | c.2026C>A p.R676S | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56681230; called by muse, mutect2
- LAMA3 | c.9325G>T p.G3109* (on ENST00000313654 / NM_198129.4; = p.G1500* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 134/640 reads (21%) | catalogued as rs757199099; called by muse, mutect2, varscan2
- LAMA5 | c.7048G>T p.A2350S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as rs768525425; called by muse, mutect2
- LAMA5 | c.5071G>T p.E1691* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as rs758070332; called by muse, mutect2, varscan2
- LAMA5 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763626394, COSV53356241; called by muse, mutect2, varscan2
- LAMB4 | c.5051G>C p.G1684A | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.714); catalogued as COSV52718686; called by muse, mutect2, varscan2
- LARP1 | c.724G>T p.G242W (on ENST00000518297 / NM_033551.3; = p.G165W on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV60424864; called by muse, mutect2
- LARP4B | c.1513A>T p.R505W | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV60222208; called by muse, mutect2, varscan2
- LCLAT1 | c.1022G>T p.R341M | Missense Mutation (SNP) | VAF 30/361 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58373758; called by muse, mutect2
- LCT | c.2381G>T p.R794L | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs765444568; called by muse, mutect2, varscan2
- LELP1 | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 42/622 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs200747820; called by muse, mutect2
- LHX8 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.474); catalogued as rs367958622; called by muse, mutect2, varscan2
- LILRA2 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV52198103, COSV99253816; called by muse, mutect2, varscan2
- LIMS2 | c.799G>C p.D267H (on ENST00000355119 / NM_001161403.3; = p.D291H on NM_017980.4) | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61441929; called by muse, mutect2
- LIN54 | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs1464347035; called by muse, mutect2, varscan2
- LMNB2 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 71/278 reads (26%) | catalogued as COSV100322405; called by muse, mutect2, varscan2
- LNPEP | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 60/605 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375167356, COSV51481719; called by muse, mutect2, varscan2
- LPIN1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 147/449 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs373506318; called by muse, mutect2, varscan2
- LRFN3 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55817564; called by muse, mutect2
- LRFN5 | c.2072C>A p.T691K | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); catalogued as rs369488450, COSV53254589, COSV53260302; called by muse, mutect2
- LRIG3 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV57869932; called by muse, mutect2, varscan2
- LRP1 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 52/428 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs748403383; called by muse, mutect2, varscan2
- LRP1B | c.13654G>T p.A4552S | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV67191054; called by muse, mutect2, varscan2
- LRP1B | c.5495A>T p.Q1832L | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67212739; called by muse, mutect2, varscan2
- LRP1B | c.2242G>T p.G748* | Nonsense Mutation (SNP) | VAF 9/101 reads (9%) | catalogued as COSV67251812; called by muse, mutect2
- LRP2 | c.5305G>T p.D1769Y | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776272091; called by muse, mutect2, varscan2
- LRRC18 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53286247; called by muse, mutect2
- LRRC37A3 | c.4070G>T p.G1357V | Missense Mutation (SNP) | VAF 45/672 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.637); catalogued as COSV58534310; called by muse, mutect2
- LRRC52 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 68/367 reads (19%) | catalogued as rs762655638, COSV54232866; called by muse, mutect2, varscan2
- LRRC7 | c.1402C>G p.Q468E (on ENST00000651989 / NM_001370785.2; = p.Q435E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50558241; called by muse, mutect2
- LRRIQ4 | c.875T>A p.L292Q | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100540361; called by muse, mutect2, varscan2
- LRRK2 | c.3346G>T p.G1116* | Nonsense Mutation (SNP) | VAF 41/309 reads (13%) | catalogued as COSV100110317, COSV54168313; called by muse, mutect2, varscan2
- LTBP3 | c.3176G>A p.R1059H | Missense Mutation (SNP) | VAF 63/554 reads (11%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.964); catalogued as rs1281800282; called by muse, mutect2, varscan2
- LTBP4 | c.4814G>T p.R1605L (on ENST00000308370 / NM_001042544.1; = p.R1568L on NM_003573.2) | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.046); catalogued as COSV52577027; called by muse, mutect2, varscan2
- LTF | c.620C>A p.P207Q | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as rs567015734, COSV51605673, COSV99207653; called by muse, mutect2, varscan2
- LZTS2 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1380292690; called by muse, mutect2
- MAGEC1 | c.2047C>A p.P683T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV53582960; called by muse, mutect2, varscan2
- MAGEC1 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs781101047; called by muse, mutect2, varscan2
- MAGEC1 | c.3124G>C p.E1042Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV53571500; called by muse, mutect2, varscan2
- MAGEC3 | c.181del p.E61Rfs*2 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | catalogued as COSV53581003; called by mutect2, pindel, varscan2
- MAGEL2 | c.3530C>G p.P1177R | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV58569710; called by muse, mutect2
- MAGI2 | c.1546C>A p.P516T | Missense Mutation (SNP) | VAF 66/754 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV104415196; called by muse, mutect2
- MAP1A | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 54/594 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55813449; called by muse, mutect2
- MAP1B | c.966C>A p.S322R | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs760289531; called by muse, mutect2
- MAP3K15 | c.1387G>C p.G463R | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.66); catalogued as COSV100135423, COSV58826900; called by muse, mutect2, varscan2
- MARCHF10 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 129/390 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV60888975; called by muse, mutect2, varscan2
- MARCHF4 | c.832G>C p.G278R | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56102586, COSV56108320; called by muse, mutect2, varscan2
- MCC | c.452A>T p.D151V | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1160702759; called by muse, mutect2, varscan2
- MCM6 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs777868882; called by muse, mutect2, varscan2
- MDGA2 | c.2572G>T p.D858Y (on ENST00000399232 / NM_001113498.2; = p.D560Y on NM_182830.4) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62083309; called by muse, mutect2
- MDGA2 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100637814; called by muse, mutect2, varscan2
- MDN1 | c.4109G>A p.R1370Q | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs1409876112, COSV65521174; called by muse, mutect2
- MEGF8 | c.5095del p.A1699Rfs*31 (on ENST00000251268 / NM_001271938.2; = p.A1632Rfs*31 on NM_001410.3) | Frame Shift Del (DEL) | VAF 109/376 reads (29%) | catalogued as COSV52094990; called by mutect2, pindel, varscan2
- MGAT4C | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs367612551; called by muse, mutect2, varscan2
- MICAL3 | c.1252G>C p.A418P | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52893529; called by muse, varscan2
- MIDEAS | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs1392831238; called by muse, mutect2, varscan2
- MIP | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1458115258; called by muse, mutect2, varscan2
- MIR9-1HG | n.322G>A | Splice Region (SNP) | VAF 33/187 reads (18%) | catalogued as rs1217513858, COSV59483825; called by muse, mutect2, varscan2
- MKI67 | c.1589G>C p.G530A | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64077091; called by muse, mutect2, varscan2
- MKRN3 | c.159G>T p.R53S | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV58809983; called by muse, mutect2, varscan2
- MKRN3 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746805239, COSV58812285; called by muse, mutect2, varscan2
- MMP14 | c.1478T>C p.V493A | Missense Mutation (SNP) | VAF 55/465 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.462); catalogued as rs992485705; called by muse, mutect2, varscan2
- MMUT | c.447C>A p.D149E | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51274366; called by muse, mutect2, varscan2
- MNDA | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as COSV100933337; called by muse, mutect2, varscan2
- MOK | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.307); catalogued as COSV51968244; called by muse, mutect2, varscan2
- MOS | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as COSV61336351; called by muse, mutect2, varscan2
- MRGPRE | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs760513724; called by muse, mutect2, varscan2
- MS4A1 | c.32C>G p.T11S | Missense Mutation (SNP) | VAF 79/399 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV61941943; called by muse, mutect2, varscan2
- MTRR | c.404G>T p.G135V (on ENST00000264668; = p.G108V on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/480 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM159484; called by muse, mutect2, varscan2
- MTX3 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV101560521; called by muse, mutect2, varscan2
- MUC16 | c.42778G>A p.V14260M | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated, low confidence (0.98); PolyPhen possibly damaging (0.479); catalogued as rs201795937; called by muse, mutect2, varscan2
- MUC16 | c.29911C>G p.L9971V | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.583); catalogued as COSV67464861; called by muse, mutect2, varscan2
- MUC16 | c.29542G>T p.A9848S | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.019); catalogued as rs537265867; called by muse, mutect2, varscan2
- MUC16 | c.13849G>C p.E4617Q | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV101198175, COSV67465081; called by muse, mutect2
- MUC16 | c.8983C>A p.P2995T | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67477601; called by muse, mutect2, varscan2
- MUC17 | c.6026C>T p.P2009L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs780828762; called by mutect2, varscan2
- MUC5B | c.15103C>T p.R5035C | Missense Mutation (SNP) | VAF 92/365 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs769579721, COSV71592640; called by muse, mutect2, varscan2
- MXRA5 | c.408C>A p.H136Q | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292503356; called by muse, mutect2, varscan2
- MYCBP2 | c.4993C>A p.L1665M (on ENST00000357337; = p.L1703M on NM_015057.5) | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62042621; called by muse, mutect2
- MYF6 | c.200dup p.L68Pfs*26 | Frame Shift Ins (INS) | VAF 46/397 reads (12%) | catalogued as rs760756094; called by mutect2, pindel, varscan2
- MYH1 | c.1737C>A p.H579Q | Missense Mutation (SNP) | VAF 104/536 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1206647156; called by muse, mutect2, varscan2
- MYH11 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 130/689 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257521; called by muse, mutect2, varscan2
- MYH4 | c.1589C>A p.P530H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55127526; called by muse, mutect2
- MYH6 | c.3793C>A p.L1265I | Missense Mutation (SNP) | VAF 88/666 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV62454295; called by muse, mutect2, varscan2
- MYH6 | c.2685+2T>C p.X895_splice | Splice Site (SNP) | VAF 50/562 reads (9%) | catalogued as rs111956421; called by muse, mutect2
- MYH7 | c.2360G>T p.R787L | Missense Mutation (SNP) | VAF 93/755 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.079); catalogued as CM031277; called by muse, mutect2, varscan2
- MYH8 | c.5014G>C p.E1672Q | Missense Mutation (SNP) | VAF 35/522 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV67975385; called by muse, mutect2
- MYH8 | c.2527C>T p.L843F | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs995598504, COSV67959594; called by muse, mutect2, varscan2
- MYO18B | c.4349G>T p.R1450L | Missense Mutation (SNP) | VAF 53/435 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV59149873, COSV99070740; called by muse, mutect2, varscan2
- MYO18B | c.6971C>A p.T2324N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs1245196255; called by muse, mutect2, varscan2
- MYO3B | c.2886C>A p.D962E | Missense Mutation (SNP) | VAF 89/475 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs955715210; called by muse, mutect2, varscan2
- MYO7A | c.5497G>T p.G1833C | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367496020, COSV68684920; called by muse, mutect2, varscan2
- MYT1L | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 29/400 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.268); catalogued as COSV101221045; called by muse, mutect2
- NABP2 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99910512; called by muse, mutect2, varscan2
- NALCN | c.3903G>C p.M1301I | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV99218941; called by muse, mutect2, varscan2
- NAV3 | c.5406G>T p.Q1802H (on ENST00000397909 / NM_001024383.2; = p.Q1780H on NM_014903.6) | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs1231054412; called by muse, mutect2, varscan2
- NBEAL1 | c.5023G>A p.E1675K | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0.057); catalogued as COSV71373850; called by muse, varscan2
- NBEAL2 | c.5336G>T p.R1779L | Missense Mutation (SNP) | VAF 96/443 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as COSV99434819; called by muse, mutect2, varscan2
- NCAPG2 | c.2480G>T p.R827L | Missense Mutation (SNP) | VAF 34/499 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs774264384, COSV51988642; called by muse, mutect2
- NCKAP5L | c.3380G>T p.G1127V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60128403, COSV60133378; called by muse, mutect2, varscan2
- NEB | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as rs1324280943, COSV51425954, COSV99426066; called by muse, mutect2, varscan2
- NEIL1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs765755581; called by muse, varscan2
- NEXMIF | c.3962C>A p.S1321Y | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV50021672; called by muse, mutect2, varscan2
- NF1 | c.3337C>A p.L1113I | Missense Mutation (SNP) | VAF 39/337 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs1185432449, CD1512856; called by muse, mutect2, varscan2
- NF1 | c.8300A>T p.Q2767L (on ENST00000358273 / NM_001042492.3; = p.Q2746L on NM_000267.3) | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV100647169; called by muse, mutect2
- NFKB2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1413174692, COSV51872383; called by muse, mutect2, varscan2
- NID1 | c.1808G>T p.R603L | Missense Mutation (SNP) | VAF 114/598 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as rs568556688, COSV51620446; called by muse, mutect2, varscan2
- NID1 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs749443587; called by muse, mutect2, varscan2
- NLRC5 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52650810; called by muse, mutect2
- NLRP14 | c.2642G>T p.R881L | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.018); catalogued as rs150675099, COSV55073118; called by muse, mutect2, varscan2
- NLRP2 | c.2575G>T p.D859Y | Missense Mutation (SNP) | VAF 150/361 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV99672675; called by muse, mutect2, varscan2
- NLRP3 | c.2678G>T p.G893V | Missense Mutation (SNP) | VAF 81/575 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.617); catalogued as COSV60232249; called by muse, mutect2, varscan2
- NME6 | c.171G>C p.Q57H (on ENST00000415053; = p.Q65H on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs1463830504; called by muse, mutect2, varscan2
- NOL4 | c.452T>A p.V151E | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99305399; called by muse, mutect2, varscan2
- NOX1 | c.673G>T p.G225* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | catalogued as COSV99471688; called by muse, mutect2, varscan2
- NPAP1 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs754053840; called by muse, mutect2, varscan2
- NPC1 | c.3295A>G p.I1099V | Missense Mutation (SNP) | VAF 110/333 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs753064951, COSV52571945; called by muse, mutect2, varscan2
- NPC1L1 | c.2216C>G p.A739G | Missense Mutation (SNP) | VAF 54/593 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1442087641; called by muse, mutect2
- NPHP4 | c.1824G>C p.E608D | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.462); catalogued as COSV65394736; called by muse, mutect2
- NPIPB9 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 36/824 reads (4%) | SIFT deleterious, low confidence (0); catalogued as rs926663585; called by muse, mutect2
- NPL | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 99/496 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs764422150; called by muse, mutect2, varscan2
- NPSR1 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 111/665 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV62200375; called by muse, mutect2, varscan2
- NPY4R | c.154A>T p.T52S | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV100966140; called by muse, mutect2
- NR1H4 | c.784G>T p.D262Y (on ENST00000551379 / NM_001206993.2; = p.D248Y on NM_005123.4) | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs750935292; called by muse, varscan2
- NR2E1 | c.172-1G>T p.X58_splice | Splice Site (SNP) | VAF 117/434 reads (27%) | catalogued as COSV64561427; called by muse, mutect2, varscan2
- NSD1 | c.6664G>A p.V2222M | Missense Mutation (SNP) | VAF 88/738 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs1472021701; called by muse, mutect2, varscan2
- NSD2 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as COSV56390196; called by muse, mutect2, varscan2
- NSUN3 | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV58935369; called by muse, varscan2
- NT5C1B | c.182C>G p.S61W | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV58398640; called by muse, mutect2, varscan2
- NTM | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 53/634 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66173989, COSV66181107; called by muse, mutect2
- NTN1 | c.224C>A p.A75E | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV51483506; called by muse, mutect2, varscan2
- NTRK1 | c.2127C>A p.D709E | Missense Mutation (SNP) | VAF 68/393 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs777306969, COSV62324762; called by muse, mutect2, varscan2
- NUCKS1 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63347795; called by muse, mutect2, varscan2
- NYNRIN | c.5603C>A p.T1868N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.705); catalogued as COSV66845024; called by muse, mutect2
- OAS2 | c.507G>T p.K169N | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.207); catalogued as rs1192089049; called by muse, mutect2
- OBI1 | c.135G>T p.W45C | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488238032; called by muse, mutect2, varscan2
- OBSCN | c.18670C>A p.L6224M | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99475311; called by muse, mutect2, varscan2
- OBSL1 | c.5509G>T p.G1837C | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.904); catalogued as COSV54707853; called by muse, mutect2, varscan2
- OFD1 | c.2992G>T p.E998* | Nonsense Mutation (SNP) | VAF 39/203 reads (19%) | catalogued as COSV57424471; called by muse, mutect2, varscan2
- OPRL1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 114/494 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767720740; called by muse, mutect2, varscan2
- OR10S1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 71/452 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101602514; called by muse, mutect2, varscan2
- OR10T2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs772691278, COSV57783296, COSV57784051; called by muse, mutect2, varscan2
- OR13A1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.042); catalogued as COSV100980935, COSV65572878; called by muse, mutect2
- OR14C36 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1406699832, COSV100507647, COSV58601906; called by muse, mutect2, varscan2
- OR14K1 | c.58del p.V20Cfs*3 | Frame Shift Del (DEL) | VAF 40/188 reads (21%) | catalogued as COSV51720815; called by mutect2, pindel, varscan2
- OR1J4 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100534331; called by muse, mutect2, varscan2
- OR1S2 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183447800, COSV100224238; called by muse, mutect2, varscan2
- OR2AG2 | c.46G>T p.G16W | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58456300; called by muse, mutect2, varscan2
- OR2AK2 | c.878G>T p.R293I | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV63560280; called by muse, mutect2
- OR2C3 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 74/507 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1246511094; called by muse, mutect2, varscan2
- OR2G6 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99080275; called by muse, mutect2
- OR2M2 | c.736A>T p.M246L | Missense Mutation (SNP) | VAF 84/543 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs780321436, COSV62898613; called by muse, mutect2, varscan2
- OR2M5 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs368493003, COSV100822766; called by muse, varscan2
- OR2M7 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99049577; called by muse, mutect2
- OR2T2 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 134/1297 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs772571406, COSV61618428; called by muse, mutect2
- OR4C11 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56354573; called by muse, mutect2, varscan2
- OR4C12 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV58859776, COSV58861018; called by muse, mutect2, varscan2
- OR4K15 | c.304A>T p.T102S (on ENST00000305051; = p.T78S on NM_001005486.1) | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV59303386; called by muse, mutect2, varscan2
- OR4K17 | c.577T>C p.Y193H | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs774437879; called by muse, varscan2
- OR51B5 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100332594; called by muse, mutect2, varscan2
- OR52D1 | c.464G>C p.S155T | Missense Mutation (SNP) | VAF 90/350 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV59487362; called by muse, mutect2, varscan2
- OR5AC2 | c.370C>G p.R124G | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62279434, COSV62279664; called by mutect2, varscan2
- OR5B21 | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV64481928; called by muse, mutect2, varscan2
- OR5D16 | c.910C>G p.R304G | Missense Mutation (SNP) | VAF 63/266 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV65721423; called by muse, mutect2, varscan2
- OR5I1 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV56885401, COSV56885694, COSV56885720; called by muse, mutect2, varscan2
- OR5J2 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56622444; called by muse, mutect2, varscan2
- OR5L2 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV65724974; called by muse, mutect2
- OR5P3 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 94/407 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV60429622; called by muse, mutect2, varscan2
- OR5T1 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV100478745; called by muse, mutect2, varscan2
- OR6K3 | c.826C>G p.R276G (on ENST00000368146; = p.R260G on NM_001005327.2) | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs141674620, COSV63745741; called by muse, mutect2, varscan2
- OR6Y1 | c.786C>G p.F262L | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100225231; called by muse, varscan2
- OR8G5 | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 87/462 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); catalogued as rs769692459; called by muse, mutect2, varscan2
- OR8U1 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1441316024, COSV100163882, COSV56413921; called by muse, varscan2
- OR9G1 | c.226T>A p.Y76N | Missense Mutation (SNP) | VAF 40/670 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV56454584; called by muse, mutect2
- OSBPL5 | c.2296G>T p.D766Y | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99720158; called by muse, mutect2, varscan2
- OSR2 | c.899G>T p.R300L (on ENST00000297565 / NM_001142462.3; = p.G273C on NM_053001.3) | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV99882756; called by muse, mutect2, varscan2
- OTOS | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as rs751533586; called by muse, mutect2, varscan2
- OTUD6A | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs754807874, COSV57972961; called by muse, mutect2, varscan2
- OVCH2 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 31/132 reads (23%) | catalogued as COSV71952792; called by muse, mutect2, varscan2
- PADI6 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.634); catalogued as COSV100639873; called by muse, mutect2, varscan2
- PAK5 | c.863C>A p.S288* | Nonsense Mutation (SNP) | VAF 31/482 reads (6%) | catalogued as COSV62027777; called by muse, mutect2
- PALD1 | c.2516G>T p.R839L | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781675921, COSV99698633; called by muse, mutect2, varscan2
- PAN3 | c.1184A>T p.K395M | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV56701098; called by muse, mutect2, varscan2
- PANX1 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 66/387 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.107); catalogued as COSV57133518, COSV57135619; called by muse, mutect2, varscan2
- PAPPA2 | c.1704C>G p.S568R | Missense Mutation (SNP) | VAF 74/506 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV100867013; called by muse, varscan2
- PAPPA2 | c.3283G>C p.A1095P | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62809378; called by muse, mutect2
- PARM1 | c.257G>T p.R86I | Missense Mutation (SNP) | VAF 75/612 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV56657564; called by muse, mutect2, varscan2
- PARP15 | c.829C>G p.P277A (on ENST00000464300 / NM_001113523.3; = p.P43A on NM_152615.2) | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.137); catalogued as COSV59971821; called by muse, mutect2, varscan2
- PASD1 | c.1735G>T p.G579W | Missense Mutation (SNP) | VAF 149/334 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64857463; called by muse, mutect2, varscan2
- PAX6 | c.1166C>G p.S389W | Missense Mutation (SNP) | VAF 138/547 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV53792205; called by muse, mutect2, varscan2
- PCDH11X | c.2314G>T p.V772L | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV100007452; called by muse, mutect2, varscan2
- PCDH15 | c.5242C>A p.P1748T | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV57374312; called by mutect2, varscan2
- PCDH15 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57321307; called by muse, mutect2, varscan2
- PCDH7 | c.970G>T p.G324W | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538540892; called by muse, mutect2, varscan2
- PCDHA10 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV100255759, COSV100256484; called by muse, mutect2, varscan2
- PCDHB10 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 123/528 reads (23%) | catalogued as COSV53379049; called by muse, mutect2, varscan2
- PCDHB13 | c.2317A>T p.N773Y | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); catalogued as rs140404643; called by muse, mutect2, varscan2
- PCDHB14 | c.1123T>G p.S375A | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.248); catalogued as COSV99506263; called by muse, mutect2
- PCDHB9 | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 167/779 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as COSV53382597; called by muse, mutect2, varscan2
- PCDHB9 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 144/724 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.272); catalogued as rs1554283173; called by muse, mutect2, varscan2
- PCDHGA2 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 80/688 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.086); catalogued as rs763629957, COSV53925943; called by muse, mutect2, varscan2
- PCDHGA3 | c.2291G>T p.R764L | Missense Mutation (SNP) | VAF 21/418 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); catalogued as COSV53893850; called by muse, mutect2
- PCDHGB6 | c.2150G>T p.R717L | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs754268147; called by muse, mutect2, varscan2
- PCDHGB7 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.171); catalogued as COSV53959052; called by muse, mutect2, varscan2
- PDE10A | c.1651C>A p.L551I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.285); catalogued as COSV63098133; called by muse, mutect2
- PDE4B | c.785C>A p.S262* | Nonsense Mutation (SNP) | VAF 28/200 reads (14%) | catalogued as COSV58501274; called by muse, mutect2, varscan2
- PDE4DIP | c.2989G>C p.D997H | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs782687976; called by muse, mutect2, varscan2
- PDGFRA | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57272210; called by muse, mutect2, varscan2
- PDPR | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 90/785 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV55353888; called by muse, mutect2, varscan2
- PDZRN3 | c.2632C>A p.Q878K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs746611865, COSV104376392; called by muse, mutect2, varscan2
- PDZRN4 | c.1267G>C p.D423H (on ENST00000402685 / NM_001164595.2; = p.D165H on NM_013377.4) | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100113583, COSV54219372; called by muse, mutect2
- PDZRN4 | c.1995G>T p.E665D (on ENST00000402685 / NM_001164595.2; = p.E407D on NM_013377.4) | Missense Mutation (SNP) | VAF 33/369 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100114146; called by muse, mutect2
- PEPD | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 54/464 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1437936452; called by muse, mutect2, varscan2
- PEX26 | c.896A>G p.Y299C | Missense Mutation (SNP) | VAF 51/349 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs745516553; called by muse, mutect2, varscan2
- PGBD2 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 184/625 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs371694592; called by muse, mutect2, varscan2
- PHF3 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100014050; called by muse, mutect2, varscan2
- PHLDB1 | c.1972G>T p.A658S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1555110066; called by muse, mutect2, varscan2
- PIAS2 | c.704A>T p.N235I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104411374; called by muse, mutect2, varscan2
- PIK3AP1 | c.2226G>C p.M742I | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.961); catalogued as COSV59531016; called by muse, mutect2
- PIK3C2A | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.04); catalogued as rs1394558881; called by muse, varscan2
- PIK3CG | c.3157del p.D1053Mfs*55 | Frame Shift Del (DEL) | VAF 45/352 reads (13%) | catalogued as COSV104418557; called by mutect2, pindel, varscan2
- PIWIL4 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV54409110, COSV54409184; called by muse, mutect2, varscan2
- PKD1 | c.5874G>T p.W1958C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs778122129; called by mutect2, varscan2
- PKD2L1 | c.2051T>A p.V684E | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100559362; called by muse, mutect2
- PKHD1L1 | c.8605+1G>T p.X2869_splice | Splice Site (SNP) | VAF 43/178 reads (24%) | catalogued as COSV101006909; called by muse, mutect2, varscan2
- PLAUR | c.721A>G p.M241V | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs759697690; called by muse, mutect2, varscan2
- PLB1 | c.3496C>G p.L1166V | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100579726; called by muse, mutect2, varscan2
- PLCE1 | c.1206+1G>T p.X402_splice | Splice Site (SNP) | VAF 39/264 reads (15%) | catalogued as rs1167799088; called by muse, mutect2, varscan2
- PLCH2 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53943791; called by muse, mutect2, varscan2
- PLCH2 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53945634; called by muse, mutect2, varscan2
- PLCL2 | c.2090G>T p.C697F (on ENST00000615277 / NM_001144382.2; = p.C571F on NM_015184.5) | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101196612; called by muse, mutect2, varscan2
- PLEC | c.2074C>G p.L692V (on ENST00000322810 / NM_201380.4; = p.L582V on NM_000445.5) | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV59616669; called by muse, mutect2, varscan2
- PLEKHG4B | c.1375G>T p.E459* (on ENST00000283426; = p.E815* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 129/731 reads (18%) | catalogued as COSV52047004; called by muse, mutect2, varscan2
- PLOD3 | c.1142A>G p.Q381R | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1161160350; called by muse, mutect2, varscan2
- PLPPR4 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV64564204; called by muse, mutect2, varscan2
- PLPPR4 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV100926807; called by muse, mutect2, varscan2
- PLXDC2 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | catalogued as COSV101023435; called by muse, mutect2, varscan2
- PLXNB3 | c.1937G>A p.C646Y | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62800139; called by muse, mutect2, varscan2
- POLE | c.6136+1G>T p.X2046_splice | Splice Site (SNP) | VAF 36/330 reads (11%) | catalogued as COSV100266620; called by muse, mutect2
- POLE | c.638A>G p.D213G | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV100266005; called by muse, mutect2, varscan2
- POLE2 | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs147671480; called by mutect2, varscan2
- POLG | c.1250+8G>T | Splice Region (SNP) | VAF 140/566 reads (25%) | catalogued as rs775109520; called by muse, mutect2, varscan2
- POTEF | c.2713G>T p.E905* | Nonsense Mutation (SNP) | VAF 155/404 reads (38%) | catalogued as COSV62542104; called by mutect2, varscan2
- POTEM | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 133/1462 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV69153161; called by muse, varscan2
- POTEM | c.331G>T p.G111W | Missense Mutation (SNP) | VAF 138/1462 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV69154762; called by muse, varscan2
- POU2F3 | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.238); catalogued as COSV52792621, COSV52798230; called by muse, mutect2, varscan2
- POU6F2 | c.764C>A p.S255Y | Missense Mutation (SNP) | VAF 92/448 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV68878265; called by muse, mutect2, varscan2
- PPP1R3A | c.2195T>C p.I732T | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99492095; called by muse, mutect2
- PPP3CA | c.316G>T p.G106* | Nonsense Mutation (SNP) | VAF 28/360 reads (8%) | catalogued as COSV100547917; called by muse, mutect2
- PPP4R3B | c.1116G>C p.M372I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV55407466; called by muse, mutect2, varscan2
- PPP4R4 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58556582; called by muse, mutect2, varscan2
- PPP6R1 | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 116/264 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV69800588; called by muse, mutect2, varscan2
- PRAMEF1 | c.1391C>G p.P464R | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); catalogued as rs61775054; called by muse, varscan2
- PRAMEF12 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1420159505; called by muse, mutect2, varscan2
- PRDM2 | c.2340C>G p.D780E | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.275); catalogued as rs751926439; called by muse, mutect2, varscan2
- PRDM9 | c.999C>A p.F333L | Missense Mutation (SNP) | VAF 117/902 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV57004578, COSV99690392; called by muse, varscan2
- PRDM9 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 118/898 reads (13%) | catalogued as COSV99691495; called by muse, varscan2
- PRDM9 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 68/366 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV57002771, COSV57005738; called by muse, varscan2
- PREX1 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100906652; called by muse, mutect2, varscan2
- PRKCI | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567380681; called by muse, mutect2, varscan2
- PRKCQ | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99036931; called by muse, mutect2, varscan2
- PRKX | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 44/442 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs753213012, COSV99468068; called by muse, mutect2
- PROX1 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54776801; called by muse, mutect2
- PRR5 | c.476G>T p.S159I (on ENST00000336985 / NM_181333.4; = p.S150I on NM_015366.4) | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV99134838; called by muse, mutect2, varscan2
- PRRC2A | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs34633614; called by muse, mutect2
- PRRC2B | c.5108G>T p.G1703V | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1353659085; called by muse, mutect2, varscan2
- PRUNE2 | c.1901T>A p.M634K | Missense Mutation (SNP) | VAF 117/469 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV65048013; called by muse, mutect2, varscan2
- PSD3 | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1226334083; called by muse, mutect2, varscan2
- PSG6 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 430/978 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.338); catalogued as rs765268203; called by muse, mutect2, varscan2
- PTF1A | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs371045580; called by muse, mutect2, varscan2
- PTPN11 | c.133G>T p.V45F | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61009437, COSV99080320; called by muse, mutect2, varscan2
- PTPN13 | c.5579C>G p.T1860R (on ENST00000411767 / NM_080683.3; = p.T1841R on NM_006264.3) | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.938); catalogued as COSV57407991; called by muse, mutect2
- PTPN14 | c.511-2A>G p.X171_splice | Splice Site (SNP) | VAF 39/270 reads (14%) | catalogued as COSV100872902; called by muse, mutect2, varscan2
- PTPRF | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 101/491 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.131); catalogued as rs764998994, COSV63442806; called by muse, mutect2, varscan2
- PTPRK | c.2419G>A p.D807N (on ENST00000368215 / NM_001291984.2; = p.D808N on NM_002844.4) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.321); catalogued as COSV63908941; called by muse, mutect2, varscan2
- PTPRZ1 | c.2057C>G p.S686C | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.319); catalogued as COSV66444206; called by muse, mutect2, varscan2
- PTPRZ1 | c.6613A>T p.I2205L | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs577909822; called by muse, mutect2, varscan2
- PVRIG | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV99443996; called by muse, mutect2, varscan2
- PXDNL | c.4378C>A p.P1460T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); catalogued as COSV100682634; called by muse, mutect2
- PXDNL | c.2590C>A p.R864S | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62476590; called by muse, mutect2, varscan2
- PZP | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54357706; called by muse, mutect2, varscan2
- QSER1 | c.1399A>G p.T467A (on ENST00000399302; = p.T596A on NM_001076786.3) | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs772380143; called by muse, mutect2, varscan2
- RAB3C | c.440T>C p.M147T | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs755641128; called by muse, mutect2, varscan2
- RAB40C | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs1567196130; called by muse, mutect2
- RAET1L | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as COSV99657767; called by muse, mutect2
- RAG1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs778391388, COSV55024800; called by muse, mutect2, varscan2
- RANBP3L | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56958296; called by muse, mutect2
- RAP1GDS1 | c.167G>C p.S56T (on ENST00000408927 / NM_001100427.2; = p.S57T on NM_021159.5) | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs17849535; called by muse, mutect2, varscan2
- RAPGEF3 | c.983G>A p.R328Q (on ENST00000389212; = p.R286Q on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/453 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1328917954; called by muse, mutect2, varscan2
- RASAL3 | c.329-1G>C p.X110_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as rs1357374653; called by muse, mutect2, varscan2
- RBBP6 | c.2186G>T p.R729L | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV60505756; called by muse, mutect2
- RBMXL3 | c.1683C>G p.D561E | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as rs868976223, COSV57751510; called by muse, mutect2, varscan2
- RFX4 | c.44-1G>T p.X15_splice | Splice Site (SNP) | VAF 10/95 reads (11%) | catalogued as rs1302521023; called by muse, mutect2, varscan2
- RFX4 | c.905C>G p.P302R (on ENST00000392842 / NM_213594.3; = p.P208R on NM_032491.6) | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99985582; called by muse, mutect2, varscan2
- RGPD3 | c.3231G>T p.W1077C | Missense Mutation (SNP) | VAF 56/564 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58747681; called by muse, mutect2, varscan2
- RGPD4 | c.3193G>T p.V1065L | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as rs1476887884, COSV61747011; called by muse, mutect2, varscan2
- RGSL1 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs755466579, COSV54257872; called by muse, mutect2, varscan2
- RHCG | c.1085C>A p.A362D | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV51515247; called by muse, mutect2, varscan2
- RHOBTB1 | c.1783G>T p.G595* | Nonsense Mutation (SNP) | VAF 90/420 reads (21%) | catalogued as COSV61959441; called by muse, mutect2, varscan2
- RIPK2 | c.173+1G>A p.X58_splice | Splice Site (SNP) | VAF 26/116 reads (22%) | catalogued as rs1379360051; called by muse, mutect2, varscan2
- ROBO1 | c.4030A>T p.R1344* | Nonsense Mutation (SNP) | VAF 38/377 reads (10%) | catalogued as rs1065217; called by muse, mutect2, varscan2
- RORB | c.650G>T p.G217V (on ENST00000396204 / NM_001365023.1; = p.G206V on NM_006914.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV65333098; called by mutect2, varscan2
- RPN1 | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56191129; called by muse, mutect2, varscan2
- RRNAD1 | c.1332del p.F445Sfs*35 | Frame Shift Del (DEL) | VAF 44/304 reads (14%) | catalogued as COSV100836938; called by mutect2, pindel, varscan2
- RS1 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 139/350 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as CM056045; called by muse, mutect2, varscan2
- RSBN1L | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.933); catalogued as COSV58509075; called by muse, mutect2, varscan2
- RSPO4 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 45/345 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs757714366, COSV99448864; called by muse, mutect2, varscan2
- RTTN | c.2173G>T p.G725C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219589196; called by muse, mutect2, varscan2
- RUFY1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as COSV100106157, COSV60163409; called by muse, mutect2, varscan2
- RUNX2 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61845750; called by muse, mutect2, varscan2
- RYR1 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1801086, CM085677, CM920613, COSV62101123; called by muse, mutect2, varscan2
- RYR1 | c.14310G>A p.M4770I | Missense Mutation (SNP) | VAF 41/458 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.089); catalogued as COSV100615653; called by muse, mutect2
- RYR2 | c.11209G>C p.A3737P | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100768512; called by muse, mutect2, varscan2
- RYR2 | c.13102G>T p.E4368* | Nonsense Mutation (SNP) | VAF 15/116 reads (13%) | catalogued as COSV100769804; called by muse, mutect2, varscan2
- SALL3 | c.2734G>T p.G912C | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV73306360; called by muse, mutect2, varscan2
- SBNO2 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1462699998; called by muse, mutect2, varscan2
- SCN1A | c.4448T>C p.I1483T (on ENST00000303395 / NM_001202435.3; = p.I1472T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD096228; called by muse, mutect2
- SCN7A | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101313295; called by muse, mutect2
- SDC3 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs370999937, COSV59581159; called by mutect2, varscan2
- SDF4 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV99767974; called by muse, mutect2, varscan2
- SDK1 | c.3050C>G p.S1017C | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1323846137, COSV67380913; called by muse, mutect2, varscan2
- SDSL | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs1367738005, COSV61884784; called by muse, mutect2, varscan2
- SEC14L4 | c.524T>G p.F175C | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs755536919; called by muse, mutect2, varscan2
- SEC23IP | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 110/508 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64832704; called by muse, mutect2, varscan2
- SELENBP1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs368168545; called by muse, mutect2, varscan2
- SELP | c.2055C>G p.S685R | Missense Mutation (SNP) | VAF 71/358 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55254801; called by muse, mutect2, varscan2
- SEM1 | c.151C>G p.P51A | Missense Mutation (SNP) | VAF 144/887 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.685); catalogued as rs770304353; called by muse, mutect2, varscan2
- SEMA5B | c.1804C>G p.P602A | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1411190777; called by muse, mutect2, varscan2
- SEMA6D | c.2572C>G p.H858D (on ENST00000316364 / NM_153618.2; = p.H796D on NM_020858.2) | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV60378502; called by muse, mutect2, varscan2
- SEPTIN11 | c.1222C>A p.Q408K | Missense Mutation (SNP) | VAF 80/416 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV99346294; called by muse, mutect2, varscan2
- SERF2 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as COSV51049323; called by muse, mutect2, varscan2
- SERPINA4 | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 42/381 reads (11%) | catalogued as COSV54070092; called by muse, mutect2, varscan2
- SERPINB13 | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV54028127; called by muse, mutect2, varscan2
- SERPINF1 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 109/384 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183672391; called by muse, mutect2, varscan2
- SETBP1 | c.2046G>T p.L682F | Missense Mutation (SNP) | VAF 209/713 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as rs1429553025; called by muse, mutect2, varscan2
- SEZ6L | c.2680G>T p.G894* | Nonsense Mutation (SNP) | VAF 16/256 reads (6%) | catalogued as COSV50670104; called by muse, mutect2
- SF3B4 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV54966667; called by muse, mutect2, varscan2
- SFXN3 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56519112; called by muse, mutect2, varscan2
- SGCZ | c.852C>G p.C284W | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66020848; called by muse, mutect2, varscan2
- SGSM1 | c.2542G>A p.D848N (on ENST00000400359 / NM_001039948.4; = p.D787N on NM_133454.3) | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs1474301279; called by muse, mutect2
3,977 further variants in this file (2,526 protein-altering or splice-affecting, 901 silent, 550 other) are not listed here.
